Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6603, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6603-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED]

PRE-OP DIAGNOSIS: Colon cancer

POST-OP DIAGNOSIS: Same

PROCEDURE: Sigmoid colectomy. [REDACTED]

ADDENDA:**Addendum**

Fluorescence in situ hybridization studies demonstrate that the adenocarcinoma has a ratio of Her-2/Neu gene to the centromere chromosome 17 of 1.19 indicating a lack of amplification in the targeted region.

Her2/neu amplification may help in identifying those patients likely to experience shorter survival when considered together with other major risk factors.

FINAL DIAGNOSIS:

COLON, SIGMOID, SEGMENTAL COLECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (3.7 CM) INVADING INTO BUT NOT THROUGH MUSCULARIS PROPRIA WITH INTRAMURAL ABSCESS. [REDACTED]
- B. SURGICAL MARGINS NEGATIVE FOR MALIGNANCY. [REDACTED]
- C. THREE (3) LYMPH NODES NEGATIVE FOR MALIGNANCY (see comment).
- D. NO ANGIOLYMPHATIC OR PERINEURAL INVASION IDENTIFIED.
- E. PATHOLOGIC STAGE: pT2 N0 MX, DUKES A.
- F. BACKGROUND COLON WITH CRYPT BRANCHING.

COMMENT:

Pericolic adipose tissue was extensively sectioned and additional sections of pericolic adipose tissue were submitted but no additional lymph nodes were identified.

SYNOPTIC - PRIMARY COLON AND RECTAL TUMORS

- A. Location: 5
- 1. Ileocecal Region
- 2. Ascending Colon
- 3. Transverse Colon
- 4. Descending Colon
- 5. Sigmoid Colon
- 6. Rectum
- B. Procedure: 1
- 1. Segmental Colectomy
- 2. Total Colectomy
- 3. Other
- C. Size of Tumor (maximum dimension): 3.7 cm
- D. Type: 1
- 1. Adenocarcinoma, NOS
- 2. Adenocarcinoma arising in a background of an adenoma.
- 3. Adenocarcinoma arising in a background of inflammatory bowel disease
- 4. Adenosquamous carcinoma
- 5. Carcinoid Tumor (Neuroendocrine Tumor)
- 6. Mucinous Adenocarcinoma
- 7. Signet ring cell type Adenocarcinoma
- 8. Neuroendocrine Carcinoma
- 9. Squamous Cell Carcinoma
- 10. Undifferentiated Carcinoma
- 11. Sarcoma
- 12. Smooth Muscle Tumor
- 13. Gastrointestinal stromal tumor
- 14. Lymphoma
- 15. Other
- E. Grade: 2
- 1. Well differentiated
- 2. Moderately differentiated
- 3. Poorly differentiated
- F. Extent of Infiltration: 3
- 1. Limited to the mucosa
- 2. Into submucosa
- 3. Involving muscularis propria
- 4. Infiltrating through muscularis propria into serosal adipose tissue
- 5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 2
- 1. Yes
- 2. No
- H. Surgical Margins Involved: 2
- 1. Yes
- 2. No
- I. Number of positive lymph nodes: 0
- J. Total number of lymph nodes examined: 3
- K. Extracapsular spread: 2
- 1. Yes
- 2. No
- L. Associated conditions: None
- 1. Ulcerative colitis.
- 2. Crohn's Disease.
- 3. History/ presence of adenomatous polyps.
- 4. Multiple polyposis syndromes.
- 5. Diverticulosis.
- M. TNM Stage: T 2 N 0 M X
- N. Dukes' Stage: 1
- 1. A (limited to mucosa and muscularis)
- 2. B (through muscularis into subserosa)
- 3. C (affecting lymph nodes)
- 4. D (metastatic)
- O. Astler-Coller Stage: 2
- 1. A (mucosa but not into muscularis propria)
- 2. B1 (muscularis propria but not through to subserosa)
- 3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
- 4. C1 (limited to muscularis propria but not through subserosa, LN positive)
- 5. C2 (invades serosal adipose tissue, LN positive)
- 6. D (metastatic disease)

Source: NCI Genomic Data Commons file 801a0d3b-d618-4b3c-906c-64fb1cef2711 (TCGA-AZ-6603.7DB6364C-AF02-40BF-B276-76B8B901C0EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).